Somatic mutation profile of tumor specimen TCGA-36-2533-01A (aliquot TCGA-36-2533-01A-01D-1526-09) from TCGA case TCGA-36-2533, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.3 years (20,187 days).
Specimen TCGA-36-2533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc9d99b2-49f1-400a-992c-dbfa035aab25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2533-10A (Blood Derived Normal), aliquot TCGA-36-2533-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a3727d6-e57f-4226-9498-1c5222ebbfbf

The open-access MAF lists 108 somatic variants for this specimen: 87 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 17, Frame Shift Del 14, In Frame Del 9, Splice Site 7, Nonsense Mutation 4, Intron 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF2B5 | c.919C>T p.R307C (on ENST00000647909; = p.R299C on NM_003907.3) | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs749256406, COSV56606014; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 57/81 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: likely pathogenic / pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADCY8 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 138/1360 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242984859, COSV53915654; called by muse, mutect2
- AEBP1 | c.2679_2681del p.N893del | In Frame Del (DEL) | VAF 26/132 reads (20%) | catalogued as rs763140394; called by pindel, varscan2
- APBB3 | c.351+1G>T p.X117_splice | Splice Site (SNP) | VAF 30/592 reads (5%) | catalogued as COSV100021542; called by muse, mutect2
- AR | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.02); catalogued as rs370893700, COSV65963354; called by muse, mutect2, varscan2
- BCR | c.1365C>G p.Y455* | Nonsense Mutation (SNP) | VAF 96/255 reads (38%) | catalogued as COSV59935193; called by muse, mutect2, varscan2
- C12orf57 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 278/542 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); catalogued as COSV57547481; called by muse, mutect2, varscan2
- CILP2 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs761069949, COSV52279773; called by muse, mutect2, varscan2
- CLMP | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 127/601 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV71650528; called by muse, mutect2, varscan2
- CORO1B | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100396812; called by muse, mutect2
- DNAI4 | c.842T>G p.L281* | Nonsense Mutation (SNP) | VAF 47/148 reads (32%) | catalogued as COSV64019750; called by muse, mutect2, varscan2
- DSE | c.670+1G>T p.X224_splice | Splice Site (SNP) | VAF 64/206 reads (31%) | catalogued as COSV59066944; called by muse, mutect2, varscan2
- EMC10 | c.273C>A p.S91R | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV58543138; called by muse, mutect2, varscan2
- ENOX1 | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 126/376 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV54915387; called by muse, mutect2, varscan2
- ESPNL | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV58037646; called by muse, mutect2, varscan2
- FAM124A | c.229C>G p.P77A (on ENST00000322475 / NM_001242312.2; = p.P113A on NM_145019.4) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV54479636; called by muse, mutect2, varscan2
- FASN | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 85/121 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1033185657, COSV60760366; called by muse, mutect2, varscan2
- FBXW12 | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 125/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56485213; called by muse, mutect2, varscan2
- FUT3 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54608036; called by muse, mutect2, varscan2
- GABRB1 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV54974186, COSV99040356, COSV99781801; called by muse, mutect2, varscan2
- GRHL2 | c.734+1G>A p.X245_splice | Splice Site (SNP) | VAF 309/728 reads (42%) | catalogued as COSV52553605; called by muse, mutect2, varscan2
- GRIA3 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 199/633 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52077819, COSV99990212; called by muse, mutect2, varscan2
- H2BC18 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 240/1384 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.109); catalogued as COSV100516098, COSV58944826; called by muse, mutect2, varscan2
- HLA-E | c.214T>A p.W72R | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64927895; called by muse, mutect2, varscan2
- HRC | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 111/609 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV53258519; called by muse, mutect2, varscan2
- IGFBP1 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV51875320; called by muse, mutect2, varscan2
- IL21R | c.827T>G p.F276C | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61972304; called by muse, mutect2, varscan2
- KRT76 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 206/556 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as COSV60121743; called by muse, mutect2, varscan2
- KRT85 | c.1349G>C p.G450A | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV57738067; called by muse, mutect2, varscan2
- LRRK2 | c.1095C>G p.H365Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV54168050; called by muse, mutect2, varscan2
- MAPK6 | c.1604T>A p.I535N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV55931434; called by muse, mutect2, varscan2
- MBD6 | c.1674_1675del p.H558Qfs*16 | Frame Shift Del (DEL) | VAF 50/366 reads (14%) | catalogued as rs929416597; called by pindel, varscan2
- MYH8 | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs140112749; called by muse, mutect2, varscan2
- MYOCD | c.2778T>A p.N926K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs762910353, COSV58510836; called by muse, mutect2, varscan2
- OR5B2 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 89/439 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as COSV56909441; called by muse, mutect2, varscan2
- ORAI3 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52691817; called by muse, mutect2, varscan2
- PCDHB4 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 35/416 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV52019672, COSV99522553; called by muse, mutect2
- PDHX | c.355A>G p.S119G | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57165827, COSV57168665; called by muse, mutect2, varscan2
- PI4K2B | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335684; called by muse, mutect2
- PLS3 | c.368-1G>A p.X123_splice | Splice Site (SNP) | VAF 21/142 reads (15%) | catalogued as COSV56781741; called by muse, mutect2
- PNN | c.1113G>C p.E371D | Missense Mutation (SNP) | VAF 92/641 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV53768215; called by muse, mutect2, varscan2
- PPM1F | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV54286004, COSV54286334; called by muse, mutect2, varscan2
- PREX1 | c.4792C>A p.Q1598K | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64256024; called by muse, mutect2, varscan2
- PTK7 | c.1171T>A p.C391S | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57851189; called by muse, mutect2, varscan2
- RBBP6 | c.3298C>T p.Q1100* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV60508108; called by muse, mutect2, varscan2
- RFX1 | c.1851+1G>T p.X617_splice | Splice Site (SNP) | VAF 35/129 reads (27%) | catalogued as COSV54333170; called by muse, mutect2, varscan2
- SALL2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as rs1299128097, COSV100444625; called by muse, mutect2, varscan2
- SALL2 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100444627; called by muse, mutect2, varscan2
- SERINC2 | c.1344_1346del p.L449del (on ENST00000373709 / NM_178865.5; = p.L453del on NM_018565.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 44/218 reads (20%) | catalogued as rs782765986; called by pindel, varscan2
- SLC26A7 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52603143; called by muse, mutect2, varscan2
- SLC27A4 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.995); catalogued as rs761056845, COSV55959957, COSV55961578; called by muse, mutect2, varscan2
- SLC51A | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV56350917, COSV56352629; called by muse, varscan2
- SRRM2 | c.5456G>A p.G1819D | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57074345, COSV57079675; called by muse, mutect2, varscan2
- SSH2 | c.2028G>T p.M676I | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV52179925; called by muse, mutect2, varscan2
- ST18 | c.2287T>A p.S763T | Missense Mutation (SNP) | VAF 177/455 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV52506910; called by muse, mutect2, varscan2
- THBS1 | c.3214C>A p.P1072T | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as COSV52955298; called by muse, mutect2, varscan2
- TMEM45A | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs146094123; called by muse, mutect2, varscan2
- TRIB3 | c.990G>A p.W330* | Nonsense Mutation (SNP) | VAF 43/165 reads (26%) | catalogued as COSV99424018; called by muse, mutect2
- UHMK1 | c.224_225del p.K75Rfs*37 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs757774011; called by mutect2, pindel, varscan2
- VIRMA | c.4662A>C p.E1554D | Missense Mutation (SNP) | VAF 188/490 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.37); catalogued as rs772231079, COSV52590344; called by muse, mutect2, varscan2
- WARS2 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52482167; called by muse, mutect2, varscan2
- ZC3H3 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 145/264 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV52794288; called by muse, mutect2, varscan2
- ZNF33B | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV63943241; called by muse, mutect2, varscan2
- ACIN1 | c.1425_1427del p.G476del | In Frame Del (DEL) | VAF 32/159 reads (20%) | called by pindel, varscan2
- AP3B1 | c.2276_2283del p.N759Ifs*2 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- BCL3 | c.1213_1214del p.Q405Vfs*61 | Frame Shift Del (DEL) | VAF 79/578 reads (14%) | called by mutect2, pindel, varscan2
- CD200R1 | c.479del p.N160Tfs*39 (on ENST00000471858 / NM_170780.3; = p.N183Tfs*39 on NM_138806.4) | Frame Shift Del (DEL) | VAF 23/144 reads (16%) | called by mutect2, pindel, varscan2
- CDIPT | c.211_221del p.T71Lfs*44 | Frame Shift Del (DEL) | VAF 120/293 reads (41%) | called by mutect2, pindel, varscan2
- CSF1 | c.1489_1490del p.V497Lfs*50 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CYP4F12 | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- FAAH2 | c.191del p.K64Rfs*2 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- GIT1 | c.2140_2141del p.S714* | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by pindel, varscan2
- GPR162 | c.763T>C p.S255P | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP1B | c.9748_9749del p.S3250Tfs*18 | Frame Shift Del (DEL) | VAF 78/483 reads (16%) | called by pindel, varscan2
- LRRC40 | c.362_365del p.P121Lfs*3 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by pindel, varscan2
- MBL2 | c.179_187+1del p.X60_splice | Splice Site (DEL) | VAF 45/356 reads (13%) | called by mutect2, pindel, varscan2
- MEGF8 | c.7915_7917del p.F2639del (on ENST00000251268 / NM_001271938.2; = p.F2572del on NM_001410.3) | In Frame Del (DEL) | VAF 16/82 reads (20%) | called by pindel, varscan2
- PPP6C | c.103_105del p.L36del | In Frame Del (DEL) | VAF 40/166 reads (24%) | called by pindel, varscan2
- RFX3 | c.247_295del p.Q83Vfs*5 | Frame Shift Del (DEL) | VAF 68/375 reads (18%) | called by mutect2, pindel
- RPL8 | c.466_468del p.K156del | In Frame Del (DEL) | VAF 88/924 reads (10%) | called by pindel, varscan2
- SRRT | c.1147_1149del p.K383del | In Frame Del (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- SYVN1 | c.1266_1268del p.T424del (on ENST00000377190 / NM_172230.3; = p.T423del on NM_032431.3) | In Frame Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- TMIGD3 | c.708_710del p.R237del (on ENST00000369717 / NM_001081976.2; = p.R318del on NM_020683.7) | In Frame Del (DEL) | VAF 50/235 reads (21%) | called by pindel, varscan2
- TYK2 | c.2461_2466+26del p.X821_splice | Splice Site (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel
- WDR17 | c.2246del p.L749Yfs*16 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- YY1AP1 | c.1823_1824del p.V608Efs*10 (on ENST00000295566 / NM_139118.2; = p.V551Efs*10 on NM_018253.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 64/448 reads (14%) | called by pindel, varscan2
- ABCB10 | c.597C>A p.I199= | Silent (SNP) | VAF 146/261 reads (56%) | catalogued as COSV60623366, COSV60624178; called by muse, mutect2, varscan2
- ABCC6 | c.2679A>C p.S893= | Silent (SNP) | VAF 68/379 reads (18%) | catalogued as COSV52747371; called by muse, mutect2, varscan2
- DPP4 | c.1947T>C p.C649= | Silent (SNP) | VAF 118/767 reads (15%) | catalogued as COSV62109319; called by muse, mutect2, varscan2
- ELOVL2 | c.63G>A p.P21= | Silent (SNP) | VAF 41/224 reads (18%) | catalogued as rs765234597, COSV61156844; called by muse, mutect2, varscan2
- FAM135B | c.2364C>A p.T788= | Silent (SNP) | VAF 46/170 reads (27%) | catalogued as COSV52723950, COSV52749363; called by muse, mutect2, varscan2
- HCAR2 | c.1032G>C p.A344= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as rs201282262, COSV61024750, COSV61025699; called by muse, mutect2, varscan2
- ITGB4 | c.1998G>A p.E666= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs1482243933, COSV52331752; called by muse, mutect2, varscan2
- LARS1 | c.1482T>A p.I494= (on ENST00000394434 / NM_020117.11; = p.I467= on NM_016460.3) | Silent (SNP) | VAF 72/381 reads (19%) | catalogued as COSV50986552; called by muse, mutect2, varscan2
- MLH1 | c.1035C>G p.T345= | Silent (SNP) | VAF 49/231 reads (21%) | catalogued as COSV51623640; called by muse, mutect2, varscan2
- NETO2 | c.1458A>G p.K486= | Silent (SNP) | VAF 78/493 reads (16%) | catalogued as COSV57455268; called by muse, mutect2, varscan2
- PHF1 | c.870G>A p.L290= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as COSV65703284; called by muse, mutect2, varscan2
- PRPF6 | c.894C>A p.L298= | Silent (SNP) | VAF 77/328 reads (23%) | catalogued as COSV53870155, COSV53877547; called by muse, mutect2, varscan2
- RSAD1 | c.1254T>A p.S418= | Silent (SNP) | VAF 67/223 reads (30%) | catalogued as rs1157220266, COSV51957088; called by muse, mutect2, varscan2
- SRC | c.411C>T p.S137= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as COSV62441008; called by muse, mutect2, varscan2
- ST6GAL1 | c.510C>G p.P170= | Silent (SNP) | VAF 117/329 reads (36%) | catalogued as COSV51473987; called by muse, mutect2, varscan2
- TRAPPC6B | c.51A>T p.G17= | Silent (SNP) | VAF 36/1195 reads (3%) | catalogued as COSV100351337; called by muse, mutect2
- XIRP1 | c.5160G>A p.G1720= | Silent (SNP) | VAF 69/364 reads (19%) | catalogued as COSV61140660; called by muse, mutect2, varscan2
- DST | c.4296+4079_4296+4112del | Intron (DEL) | VAF 15/178 reads (8%) | called by mutect2, pindel
- NXT2 | chrX:109535969 C>A | 5'Flank (SNP) | VAF 43/218 reads (20%) | catalogued as COSV54297236; called by muse, mutect2, varscan2
- TMEM71 | c.814+147C>G | Intron (SNP) | VAF 52/626 reads (8%) | catalogued as COSV100785712; called by muse, mutect2
- TTN | c.10360+4517C>A | Intron (SNP) | VAF 32/94 reads (34%) | catalogued as COSV60297638; called by muse, mutect2, varscan2
